Gene-level copy-number profile of tumor specimen TCGA-BL-A0C8-01A from TCGA case TCGA-BL-A0C8, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage I; Age at diagnosis: 73.4 years (26,819 days).
Specimen TCGA-BL-A0C8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.02d3b1e9-adaa-4722-8579-b69999e7ff37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BL-A0C8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/326e3cb1-3016-43df-a749-6ec3b5d95caa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,373; copy number 3: 31,244; copy number 4: 12,510; copy number 5: 6,625; copy number 6: 1,428; copy number 7: 215; copy number 8: 207; copy number 9: 38; copy number 10: 15; copy number 11: 31; copy number 12: 52; copy number 20: 10; copy number 21: 28; copy number 25: 19; copy number 30: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BL-A0C8-01A-11D-A273-01): tumor purity 0.59, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 610 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,065,657–18,748,866, 9 genes, copy number 8: LINC01654, IGSF21, AL365209.1, IGSF21-AS1, AL591896.1, KLHDC7A, DYNLL1P3, AL031737.1, PAX7.
- chr1:116,909,149–117,778,506, 22 genes, copy number 7: AL157904.1, PTGFRN, RNA5SP55, CD101, AL445231.1, TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525, AL358072.1, MAN1A2, AL157902.2, VPS25P1, AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1.
- chr1:160,931,739–161,309,968, 31 genes, copy number 11: AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ.
- chr1:199,752,491–201,228,952, 33 genes, copy number 8: AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1, CCNQP1, LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1.
- chr3:11,790,442–12,788,671, 24 genes, copy number 20–30: TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17.
- chr3:45,676,369–46,582,457, 28 genes, copy number 21: LIMD1-AS1, SACM1L, RN7SL145P, AC098476.1, SLC6A20, LZTFL1, AC099782.1, SDHDP4, CCR9, Y_RNA, FYCO1, CXCR6, XCR1, NRBF2P2, FLT1P1, CCR3, CCR1, UQCRC2P1, CCR2, CCR5AS, CCR5, CCRL2, LINC02009, LTF, RTP3, LRRC2, LRRC2-AS1, TDGF1.
- chr4:1,617,915–2,242,276, 18 genes, copy number 8 (within-gene range 4–8): FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2.
- chr5:132,673,986–133,720,934, 36 genes, copy number 9 (within-gene range 4–9): IL4, AC004039.1, KIF3A, CCNI2, SEPTIN8, SOWAHA, AC004775.1, SHROOM1, RNA5SP192, GDF9, UQCRQ, LEAP2, AFF4, AC010240.2, Y_RNA, ATP6V0E1P1, AC010240.3, AC010240.1, Y_RNA, ZCCHC10, AC113410.1, AC113410.5, AC113410.4, HSPA4, AC113410.3, AC113410.2, AC010307.2, AC010307.1, FSTL4, AC010307.3, AC010307.4, AC010608.1, MIR1289-2, AC010608.3, AC010608.2, AC005178.1.
- chr5:135,033,280–135,358,219, 1 gene, copy number 8 (within-gene range 5–8): C5orf66.
- chr5:135,120,526–137,598,379, 42 genes, copy number 8 (within-gene range 4–8): AC008406.2, AC008406.1, C5orf66-AS2, MACROH2A1, AC026691.1, DCANP1, TIFAB, AC022092.1, NEUROG1, AC034206.1, CXCL14, SLC25A48, SLC25A48-AS1, AC011431.1, MIR5692C1, AC114296.1, IL9, AC002428.2, AC002428.1, LECT2, FBXL21P, TGFBI, VTRNA2-1, Vault, SMAD5-AS1, AC009014.4, SMAD5, AC009014.2, AC009014.3, AC009014.1, SMIM32, TRPC7, TRPC7-AS1, TRPC7-AS2, AC063980.1, HSPD1P18, HNRNPA1P13, AC112178.1, AC109439.1, ANKRD49P3, RNA5SP193, SPOCK1.
- chr5:159,698,586–160,487,426, 20 genes, copy number 7: LINC01847, ADRA1B, GAPDHP40, Y_RNA, TTC1, AC068657.1, PWWP2A, FABP6, FABP6-AS1, AC112191.1, CCNJL, AC112191.2, AC112191.3, C1QTNF2, ZBED8, SLU7, PTTG1, MIR3142HG, MIR3142, MIR146A.
- chr5:160,613,873–160,692,889, 2 genes, copy number 7: AC008456.1, AC011363.1.
- chr6:43,295,694–44,155,519, 41 genes, copy number 7: SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, AL359813.1, AL359813.2, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B.
- chr7:2,679,522–4,269,000, 13 genes, copy number 8 (within-gene range 5–8): AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1.
- chr8:79,520,145–79,871,759, 8 genes, copy number 8: AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P.
- chr8:99,960,936–101,669,726, 54 genes, copy number 7–12 (within-gene range 5–12): RGS22, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1.
- chr8:101,686,547–101,689,093, 1 gene, copy number 7: AP000426.1.
- chr8:124,450,820–125,541,373, 25 genes, copy number 7 (within-gene range 5–7): TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1.
- chr9:15,553,043–16,061,663, 1 gene, copy number 9 (within-gene range 2–9): CCDC171.
- chr9:15,776,181–15,776,286, 1 gene, copy number 9: RNU6-14P.
- chr9:105,025,932–105,239,221, 1 gene, copy number 7 (within-gene range 4–7): AL591506.1.
- chr9:105,244,622–106,843,866, 19 genes, copy number 7: SLC44A1, FSD1L, RALGAPA1P1, AL158070.1, FKTN, AL158070.2, TAL2, TMEM38B, AL592437.1, DEPDC1P2, SLC25A6P5, LINC01505, AL732323.1, AL451140.1, MIR8081, AL512649.2, RN7SKP77, AL512649.1, RNA5SP292.
- chr10:2,936,021–3,991,259, 24 genes, copy number 7: AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1, LINC02639, LINC02660, MIR6078.
- chr10:27,775,186–27,999,079, 1 gene, copy number 8 (within-gene range 5–8): ARMC4.
- chr10:27,904,209–28,941,910, 24 genes, copy number 8 (within-gene range 5–8): RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1, WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308.
- chr10:79,892,148–81,137,335, 39 genes, copy number 8: PGGT1BP2, AL512662.1, BMS1P21, MBL1P, SFTPD, SFTPD-AS1, ZNRF2P3, DPY19L2P5, AL356095.1, C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9, ANXA11, LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14, AC021028.1, SH2D4B, LINC02655, RPS7P9, AC027673.1, FARSBP1, WARS2P1, RPA2P2.
- chr10:86,395,187–87,010,126, 19 genes, copy number 8 (within-gene range 6–8): AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11.
- chr17:47,603,860–48,430,275, 38 genes, copy number 7 (within-gene range 4–7): AC025682.1, KPNB1, AC015674.1, TBKBP1, TBX21, OSBPL7, MRPL10, LRRC46, SCRN2, SP6, AC018521.3, AC018521.7, AC018521.5, SP2, SP2-AS1, AC018521.6, PNPO, AC018521.1, AC018521.2, PRR15L, CDK5RAP3, AC018521.4, COPZ2, MIR152, NFE2L1-DT, NFE2L1, AC004477.1, AC004477.2, CBX1, RNU6-1201P, SNX11, SKAP1, MIR1203, SKAP1-AS1, RNU6-1152P, THRA1/BTR, AC036222.2, U3.
- chr17:50,464,496–51,171,744, 35 genes, copy number 12: CHAD, AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
